Somatic mutation profile of tumor specimen TCGA-MJ-A68H-01A (aliquot TCGA-MJ-A68H-01A-11D-A307-09) from TCGA case TCGA-MJ-A68H, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 57.8 years (21,105 days).
Specimen TCGA-MJ-A68H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c29f964-3546-4183-8dbe-f389e3e11a9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MJ-A68H-10A (Blood Derived Normal), aliquot TCGA-MJ-A68H-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7de6f33-72d5-4a2b-9f56-3212985e54a7

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 15, Intron 2, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS6 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV100068399; called by muse, mutect2, varscan2
- AL121899.2 | c.1189G>T p.G397C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101198449, COSV67350879; called by muse, mutect2, varscan2
- ASTN1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); catalogued as COSV99921597; called by muse, mutect2, varscan2
- ATP5MF | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs891850053, COSV52853813, COSV99461718; called by muse, mutect2, varscan2
- BEND4 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.523); catalogued as COSV101549744; called by muse, mutect2, varscan2
- BRD2 | c.2324G>A p.S775N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100875691; called by muse, mutect2, varscan2
- CEP128 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53677830; called by muse, mutect2, varscan2
- CNTRL | c.4796T>C p.L1599S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1252283242, COSV99442339; called by muse, mutect2, varscan2
- CSGALNACT1 | c.878G>C p.R293T | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100174968; called by muse, mutect2, varscan2
- CTNND1 | c.2330C>G p.S777C (on ENST00000399050 / NM_001085458.2; = p.S771C on NM_001331.3) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV62387062; called by muse, mutect2, varscan2
- ELP3 | c.1412T>C p.I471T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV99833972; called by muse, mutect2, varscan2
- FARSB | c.883A>G p.K295E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99918376; called by muse, mutect2, varscan2
- FCRLB | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100396187; called by muse, mutect2
- HAS1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs777058982, COSV55788668; called by muse, mutect2, varscan2
- ICE2 | c.2809A>G p.T937A | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs779625188, COSV99831529; called by muse, mutect2, varscan2
- IFI35 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs777691679, COSV99887786; called by mutect2, varscan2
- IKZF1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1483931742, COSV58791022; called by muse, mutect2, varscan2
- IQCG | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99502327; called by muse, mutect2, varscan2
- KCNN2 | c.577A>T p.I193L (on ENST00000264773; = p.I405L on NM_021614.4) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV99299754; called by muse, mutect2
- KIF1A | c.4090C>T p.R1364W (on ENST00000320389 / NM_001379639.1; = p.R1356W on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100240925; called by muse, mutect2, varscan2
- KMT2A | c.9203C>T p.P3068L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV100628824; called by muse, mutect2, varscan2
- MARK2 | c.2162A>G p.N721S (on ENST00000402010 / NM_001039469.2; = p.N657S on NM_004954.5) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100036196; called by muse, mutect2, varscan2
- OR51Q1 | c.770T>A p.M257K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100332925; called by muse, mutect2, varscan2
- PARN | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV58371649; called by muse, mutect2, varscan2
- PNPLA7 | c.382A>T p.K128* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99480673; called by muse, mutect2, varscan2
- PPP1R15B | c.1603C>A p.H535N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV100916333; called by muse, mutect2
- RABL6 | c.1501A>C p.I501L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.031); catalogued as rs759242672, COSV100273328; called by muse, mutect2, varscan2
- SLC35A5 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1343510824, COSV53727484, COSV99656789; called by muse, mutect2, varscan2
- SOS1 | c.3374C>A p.T1125N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV101216923; called by muse, mutect2
- TRPM2 | c.3596G>A p.R1199Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs773645469, COSV100308783, COSV55965553; called by muse, mutect2, varscan2
- ZNF468 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99700561; called by muse, mutect2, varscan2
- ZNF765 | c.712T>G p.L238V | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV101125476; called by muse, mutect2, varscan2
- MAPK1 | c.262_264del p.D88del | In Frame Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- USH2A | c.7706_7707dup p.L2570Ifs*8 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- CFAP161 | c.900G>A p.T300= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs371766165; called by muse, mutect2, varscan2
- CFAP45 | c.228A>G p.P76= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100928580; called by muse, mutect2, varscan2
- COG8 | c.1278C>T p.P426= | Silent (SNP) | VAF 57/72 reads (79%) | catalogued as COSV99650724; called by muse, mutect2, varscan2
- DNAH9 | c.3393C>T p.S1131= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs747340817, COSV99305832; called by muse, mutect2, varscan2
- DSCAM | c.117C>T p.T39= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV101260113; called by muse, mutect2, varscan2
- GSTZ1 | c.393C>T p.A131= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99374449; called by muse, mutect2, varscan2
- HAUS4 | c.663G>A p.K221= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99246894; called by muse, mutect2, varscan2
- ITGB5 | c.888C>T p.H296= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1233312912, COSV99950267; called by muse, mutect2, varscan2
- LRRC8A | c.1282C>T p.L428= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99396590; called by muse, mutect2, varscan2
- RAB40C | c.696C>T p.N232= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs574577493, COSV50193264; called by muse, mutect2, varscan2
- ROBO2 | c.2619G>A p.L873= | Silent (SNP) | VAF 24/187 reads (13%) | catalogued as COSV100166723; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.309C>T p.F103= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99541601; called by muse, mutect2, varscan2
- SOX7 | c.501C>T p.P167= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs563553563, COSV58731690; called by muse, mutect2, varscan2
- TNFSF14 | c.96G>A p.S32= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs377255029; called by muse, mutect2, varscan2
- ZFC3H1 | c.1980C>T p.N660= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV101110532; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1233G>A | Intron (SNP) | VAF 22/37 reads (59%) | catalogued as rs764055958, COSV100324053; called by muse, mutect2
- SYNJ2 | c.3744+869G>A | Intron (SNP) | VAF 30/92 reads (33%) | catalogued as COSV100840198; called by muse, mutect2, varscan2
